Somatic mutation profile of tumor specimen 0DHOJ5 from CCDI case PBBTND, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant tumor, spindle cell type; Tissue or organ of origin: Mandible; Age at diagnosis: 18.8 years (6,876 days).
Specimen 0DHOJ5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b5ddfc0-d5e1-438b-ba9b-191ed814ef81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHOH0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06df7313-b691-406b-b97e-b2104f7322d7

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BEST2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 253/520 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as rs1443513308; called by muse, varscan2
- C13orf42 | c.26T>C p.F9S | Missense Mutation (SNP) | VAF 270/548 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- KDM5B | c.3782A>G p.N1261S | Missense Mutation (SNP) | VAF 406/738 reads (55%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, varscan2
- UGT2A3 | c.82G>C p.V28L | Missense Mutation (SNP) | VAF 598/1548 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, varscan2
- ERICH3 | c.1254T>C p.T418= | Silent (SNP) | VAF 454/1698 reads (27%) | called by muse, varscan2
- PCDHA12 | c.810C>T p.D270= | Silent (SNP) | VAF 114/1026 reads (11%) | catalogued as rs1227830598, COSV100250622; called by muse, varscan2
- TSPEAR | c.828G>A p.P276= | Silent (SNP) | VAF 229/566 reads (40%) | catalogued as rs371022077; called by muse, varscan2
